Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7180, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7180-01A (Primary Tumor).

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) "LINGUAL NERVE":
Peripheral nerve segment, no tumor present.
- (B) "LEFT LINGUAL TONGUE BASE":
Lingual mucosa and underlying connective tissue,
no tumor present.
- (C) "TEETH":
Multiple teeth. (Gross only).
- (D) TOTAL GLOSSECTOMY, BILATERAL NECK DISSECTION AND PARTIAL MANDIBULECTOMY:
INVASIVE SQUAMOUS CARCINOMA INVOLVING TONGUE; RESECTION
MARGINS FREE OF TUMOR. (SEE COMMENT)
Tongue, status post prior surgery.
Floor of mouth, no tumor present.
Left submandibular gland, no tumor present.
Seventeen regional lymph nodes, no tumor present.

COMMENT

The cytological/histological features of this neoplasm are those of an invasive squamous carcinoma. Tumor involving the right side of the tongue is relatively well-differentiated (grade I-II). Tumor involving the left side of the tongue is somewhat less well-differentiated (grade II-III). In both cases, tumor invades deeply into the underlying connective tissues and skeletal muscle. No unequivocal lympho-vascular invasion or perineural invasion by tumor is identified. It is unclear whether this represents a single pathological process extensively involving the tongue versus multifocal primary squamous carcinoma. The final resection margins and the regional lymph nodes are free of tumor.

[REDACTED]

SPECIMEN

- (A) "LINGUAL NERVE":
- (B) "LEFT LINGUAL TONGUE BASE":
- (C) "TEETH":
- (D) TOTAL GLOSSECTOMY, BILATERAL NECK DISSECTION AND PARTIAL MANDIBULECTOMY:

SNOMED CODES

T-53000,M-80703

Source: NCI Genomic Data Commons file 666b279c-0c04-47d2-8b8f-cbbcc9a21443 (TCGA-CV-7180.90C5DD0D-F4F1-48B7-8A04-6176868F31B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).